Somatic mutation profile of tumor specimen TCGA-V5-AASV-01A (aliquot TCGA-V5-AASV-01A-11D-A387-09) from TCGA case TCGA-V5-AASV, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 67.2 years (24,559 days).
Specimen TCGA-V5-AASV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) efe15ff7-2230-42aa-a6c5-48c77f6c1199.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-V5-AASV-10A (Blood Derived Normal), aliquot TCGA-V5-AASV-10A-01D-A38A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/13186974-be25-4bab-8b3f-d70eca574a09

The open-access MAF lists 133 somatic variants for this specimen: 105 protein-altering or splice-affecting, 25 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 68, Silent 25, Frame Shift Del 13, Nonsense Mutation 8, In Frame Del 7, Frame Shift Ins 4, Splice Site 3, Intron 2, Splice Region 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASXL1 | c.2077C>T p.R693* | Nonsense Mutation (SNP) | VAF 36/90 reads (40%) | catalogued as rs373221034, COSV60102332; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 24/82 reads (29%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- SMARCA4 | c.2343G>T p.M781I | Missense Mutation (SNP) | VAF 12/53 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60787487, COSV60798909, COSV60801851; called by muse, mutect2, varscan2
- ADGRL2 | c.2636G>A p.R879Q (on ENST00000370717 / NM_001366005.1; = p.R866Q on NM_012302.4) | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs373312947; called by muse, mutect2, varscan2
- AFF1 | c.1477G>A p.E493K | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.949); catalogued as rs763409340, COSV57119579; called by muse, mutect2, varscan2
- ATRN | c.2930A>G p.Y977C | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as rs780239295; called by muse, mutect2, varscan2
- CYP4F8 | c.446G>A p.R149H | Missense Mutation (SNP) | VAF 101/199 reads (51%) | SIFT tolerated (0.09); PolyPhen benign (0.258); catalogued as rs774281339; called by muse, mutect2, varscan2
- DENND1B | c.1519C>T p.R507C | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as rs144900954; called by muse, mutect2, varscan2
- DLC1 | c.51G>A p.W17* | Nonsense Mutation (SNP) | VAF 18/66 reads (27%) | catalogued as rs201093868; called by muse, mutect2, varscan2
- DYNC2H1 | c.923G>A p.R308H | Missense Mutation (SNP) | VAF 41/120 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as COSV62093166; called by muse, mutect2, varscan2
- EPHB6 | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776478976, COSV67417892; called by muse, mutect2, varscan2
- EPX | c.462_464del p.N154del | In Frame Del (DEL) | VAF 24/58 reads (41%) | catalogued as rs750121261; called by pindel, varscan2
- ERICH1 | c.1120G>A p.D374N | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0.02); catalogued as COSV100033176; called by muse, mutect2, varscan2
- EXOSC8 | c.45_47del p.R16del | In Frame Del (DEL) | VAF 8/34 reads (24%) | catalogued as rs771058109; called by mutect2, pindel, varscan2
- FAM47C | c.1293del p.K432Rfs*393 | Frame Shift Del (DEL) | VAF 73/130 reads (56%) | catalogued as COSV63723515; called by mutect2, pindel, varscan2
- FAM83B | c.586G>A p.G196S | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.071); catalogued as rs766860593; called by muse, mutect2, varscan2
- FANCM | c.1147T>C p.Y383H | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.251); catalogued as rs766761905; called by muse, mutect2, varscan2
- FCHO2 | c.1317_1319del p.S442del | In Frame Del (DEL) | VAF 67/169 reads (40%) | catalogued as rs1396368936; called by pindel, varscan2
- FLG | c.8735C>G p.S2912C | Missense Mutation (SNP) | VAF 46/178 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as COSV64240480; called by muse, mutect2, varscan2
- G3BP1 | c.1270C>T p.R424* | Nonsense Mutation (SNP) | VAF 16/44 reads (36%) | catalogued as rs1402025416; called by muse, mutect2, varscan2
- GTF3C2 | c.730C>T p.R244W | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.306); catalogued as rs770595929, COSV53126056; called by muse, mutect2, varscan2
- HMOX1 | c.200G>A p.R67H | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.044); catalogued as rs753863879; called by muse, mutect2, varscan2
- HRCT1 | c.16G>A p.G6R | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.957); catalogued as rs1165390382; called by muse, varscan2
- JAK2 | c.3365G>A p.R1122Q | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.071); catalogued as rs775495966, COSV101070359, COSV67595294, COSV67618949; called by muse, mutect2, varscan2
- KCND2 | c.1834G>A p.D612N | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.037); catalogued as rs151258092, CM1413104; called by muse, mutect2, varscan2
- MUC16 | c.7733C>A p.P2578Q | Missense Mutation (SNP) | VAF 46/152 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as COSV67455293; called by muse, mutect2, varscan2
- NSD1 | c.5384del p.P1795Qfs*26 | Frame Shift Del (DEL) | VAF 26/52 reads (50%) | catalogued as COSV61785386; called by mutect2, pindel, varscan2
- NTM | c.287C>T p.T96M | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.75); catalogued as rs758413842, COSV66198956; called by muse, mutect2, varscan2
- OR51G2 | c.586G>A p.D196N | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.813); catalogued as rs771383654, COSV100432203; called by muse, mutect2, varscan2
- OTOP1 | c.970G>A p.A324T | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.38); PolyPhen benign (0.04); catalogued as rs200213513, COSV56390815; called by muse, mutect2, varscan2
- PARP10 | c.682C>T p.R228* | Nonsense Mutation (SNP) | VAF 19/54 reads (35%) | catalogued as rs372202325; called by muse, mutect2, varscan2
- PFKFB4 | c.1206C>A p.F402L | Missense Mutation (SNP) | VAF 15/43 reads (35%) | PolyPhen possibly damaging (0.805); catalogued as COSV99219797; called by muse, mutect2, varscan2
- PIK3C3 | c.521G>A p.R174H | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs376188539; called by muse, mutect2, varscan2
- POLR1C | c.406_409del p.D136Lfs*28 | Frame Shift Del (DEL) | VAF 20/62 reads (32%) | catalogued as rs1342828147; called by pindel, varscan2
- RAMP1 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 37/68 reads (54%) | SIFT tolerated (0.09); PolyPhen benign (0.039); catalogued as COSV54538192; called by muse, mutect2, varscan2
- RGS19 | c.188G>A p.R63Q | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.41); PolyPhen benign (0.011); catalogued as rs1451841663; called by muse, mutect2, varscan2
- SCRT1 | c.41C>T p.A14V | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.562); catalogued as COSV59780698; called by muse, mutect2, varscan2
- SH2D4A | c.1083_1085del p.L362del | In Frame Del (DEL) | VAF 28/84 reads (33%) | catalogued as rs748097834; called by pindel, varscan2
- SLC4A9 | c.1909_1912del p.T637Lfs*11 (on ENST00000507527 / NM_001258428.2; = p.T613Lfs*11 on NM_031467.3) | Frame Shift Del (DEL) | VAF 8/41 reads (20%) | catalogued as rs751158024; called by mutect2, pindel, varscan2
- SLU7 | c.416G>A p.R139Q | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.054); catalogued as rs756490598; called by muse, mutect2, varscan2
- SMARCA5 | c.1071T>A p.D357E | Missense Mutation (SNP) | VAF 56/74 reads (76%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.53); catalogued as COSV51645523; called by muse, mutect2, varscan2
- SORBS2 | c.2119C>T p.R707W | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs201392254, COSV52993569; called by muse, mutect2, varscan2
- SSH3 | c.792G>A p.G264= | Splice Region (SNP) | VAF 17/61 reads (28%) | catalogued as rs1565089199; called by muse, mutect2, varscan2
- ST8SIA4 | c.527A>T p.E176V | Missense Mutation (SNP) | VAF 12/34 reads (35%) | PolyPhen possibly damaging (0.801); catalogued as COSV51506903; called by muse, mutect2
- TESC | c.407G>A p.R136Q | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.228); catalogued as rs1401185009, COSV58810786; called by muse, mutect2, varscan2
- TEX11 | c.1273G>A p.A425T (on ENST00000344304; = p.A410T on NM_031276.3) | Missense Mutation (SNP) | VAF 75/111 reads (68%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs1392568993; called by muse, mutect2, varscan2
- TLN1 | c.6721C>T p.R2241W | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); catalogued as rs750965317; called by muse, mutect2, varscan2
- VANGL2 | c.268C>T p.R90C | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); catalogued as rs149889263; called by muse, mutect2, varscan2
- VWCE | c.1466del p.P489Hfs*11 | Frame Shift Del (DEL) | VAF 33/117 reads (28%) | catalogued as rs753714493; called by mutect2, pindel, varscan2
- ZNF12 | c.1169_1171del p.F390del (on ENST00000405858 / NM_016265.4; = p.F352del on NM_006956.3) | In Frame Del (DEL) | VAF 16/80 reads (20%) | catalogued as rs764820353; called by mutect2, pindel, varscan2
- ZSCAN18 | c.1022C>T p.A341V | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.052); catalogued as rs1429150434, COSV53731607; called by muse, mutect2, varscan2
- AP1S1 | c.94G>A p.V32M | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- ASB8 | c.843_846del p.K281Nfs*6 | Frame Shift Del (DEL) | VAF 9/27 reads (33%) | called by mutect2, pindel, varscan2
- BARD1 | c.390_391del p.S131Ffs*3 | Frame Shift Del (DEL) | VAF 25/55 reads (45%) | called by mutect2, pindel, varscan2
- BCKDHB | c.634-1G>A p.X212_splice | Splice Site (SNP) | VAF 65/232 reads (28%) | called by muse, mutect2, varscan2
- BID | c.610_612del p.K204del (on ENST00000317361 / NM_197966.2; = p.K158del on NM_001196.4) | In Frame Del (DEL) | VAF 16/55 reads (29%) | called by pindel, varscan2
- CARMIL3 | c.2453C>A p.A818E | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CCDC180 | c.859G>A p.E287K | Missense Mutation (SNP) | VAF 30/45 reads (67%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CLEC14A | c.139C>T p.R47W | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- CNTN6 | c.1678G>C p.G560R | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COMP | c.931G>A p.A311T | Missense Mutation (SNP) | VAF 39/64 reads (61%) | SIFT deleterious (0.03); PolyPhen benign (0.213); called by muse, mutect2, varscan2
- CSMD1 | c.2992G>T p.A998S (on ENST00000520002; = p.A997S on NM_033225.6) | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DOK3 | c.214A>C p.I72L | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- EFEMP1 | c.852G>C p.E284D | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ELAVL1 | c.884_885del p.Y295* | Frame Shift Del (DEL) | VAF 19/68 reads (28%) | called by mutect2, pindel, varscan2
- ESPL1 | c.303_304del p.F102Cfs*39 | Frame Shift Del (DEL) | VAF 6/28 reads (21%) | called by pindel, varscan2
- FAP | c.709T>C p.S237P | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- FEM1B | c.574C>T p.H192Y | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- FOXC1 | c.293_295del p.K98del | In Frame Del (DEL) | VAF 38/72 reads (53%) | called by pindel, varscan2
- FOXP2 | c.2004-2A>T p.X668_splice | Splice Site (SNP) | VAF 15/52 reads (29%) | called by muse, mutect2, varscan2
- INPPL1 | c.3149dup p.P1051Sfs*34 | Frame Shift Ins (INS) | VAF 29/84 reads (35%) | called by mutect2, pindel, varscan2
- KANSL1 | c.1139T>A p.L380* | Nonsense Mutation (SNP) | VAF 48/76 reads (63%) | called by muse, mutect2, varscan2
- KIF15 | c.3270G>T p.Q1090H | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- KLHL30 | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 35/47 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- KMT2B | c.3003del p.Y1002Tfs*7 | Frame Shift Del (DEL) | VAF 13/55 reads (24%) | called by mutect2, pindel, varscan2
- KMT2D | c.9872_9882del p.P3291Hfs*6 | Frame Shift Del (DEL) | VAF 13/40 reads (33%) | called by mutect2, varscan2
- MEX3A | c.556G>A p.V186M | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MTR | c.19G>T p.D7Y | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- NOTCH1 | c.467dup p.P157Afs*99 | Frame Shift Ins (INS) | VAF 43/82 reads (52%) | called by mutect2, pindel, varscan2
- PAQR8 | c.703T>G p.C235G | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- PIK3C2B | c.109C>G p.L37V | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- PIP | c.191A>G p.E64G | Missense Mutation (SNP) | VAF 37/75 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLVAP | c.898G>T p.E300* | Nonsense Mutation (SNP) | VAF 16/56 reads (29%) | called by muse, mutect2, varscan2
- PRKDC | c.2138_2139del p.E713Gfs*4 | Frame Shift Del (DEL) | VAF 31/178 reads (17%) | called by pindel, varscan2
- PTK2B | c.205_207del p.X69_splice | Splice Site (DEL) | VAF 13/48 reads (27%) | called by mutect2, pindel, varscan2
- ROR1 | c.2108A>G p.E703G | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- SDCBP | c.132T>C p.N44= | Splice Region (SNP) | VAF 33/113 reads (29%) | called by muse, mutect2, varscan2
- SIM1 | c.2233C>A p.L745M | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- SOX9 | c.407G>A p.S136N | Missense Mutation (SNP) | VAF 62/110 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- ST6GAL2 | c.1074C>A p.D358E | Missense Mutation (SNP) | VAF 62/116 reads (53%) | PolyPhen benign (0.02); called by muse, mutect2, varscan2
- TBL1XR1 | c.1107C>A p.D369E | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- TCHH | c.351A>C p.E117D | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.468); called by muse, mutect2, varscan2
- TIAM1 | c.3977G>T p.W1326L | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- TMEM176B | c.316G>T p.V106L | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- TNR | c.979G>T p.A327S | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.99); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- TRAJ29 | chr14:22513997 del AAGT | Missense Mutation (DEL) | VAF 26/72 reads (36%) | called by pindel, varscan2
- TRIL | c.496G>A p.A166T | Missense Mutation (SNP) | VAF 57/127 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- UGT3A2 | c.37_40del p.L13Sfs*13 | Frame Shift Del (DEL) | VAF 18/73 reads (25%) | called by pindel, varscan2*
- UNC13C | c.2197C>T p.Q733* | Nonsense Mutation (SNP) | VAF 11/26 reads (42%) | called by muse, mutect2, varscan2
- VIRMA | c.1929dup p.T644Yfs*8 | Frame Shift Ins (INS) | VAF 28/129 reads (22%) | called by mutect2, pindel, varscan2
- ZNF337 | c.1467dup p.C490Mfs*11 | Frame Shift Ins (INS) | VAF 6/67 reads (9%) | called by mutect2, pindel
- ZNF493 | c.256G>A p.E86K | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- ZNF521 | c.2395C>A p.Q799K | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- ZNF682 | c.1135A>T p.K379* | Nonsense Mutation (SNP) | VAF 44/82 reads (54%) | called by muse, mutect2, varscan2
- ZNF682 | c.367T>C p.C123R | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- C11orf1 | c.166C>A p.R56= | Silent (SNP) | VAF 13/57 reads (23%) | catalogued as COSV52787941; called by muse, mutect2, varscan2
- CARNS1 | c.1665C>T p.F555= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as rs138253032; called by muse, varscan2
- CHD8 | c.1026G>T p.L342= (on ENST00000646647 / NM_001170629.2; = p.L63= on NM_020920.4) | Silent (SNP) | VAF 37/107 reads (35%) | catalogued as rs1274320771; called by muse, mutect2, varscan2
- CILP2 | c.951G>A p.G317= | Silent (SNP) | VAF 39/120 reads (33%) | called by muse, mutect2, varscan2
- COQ8B | c.723C>T p.P241= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as rs55973839; called by muse, varscan2
- CPN2 | c.144G>A p.P48= | Silent (SNP) | VAF 16/30 reads (53%) | catalogued as rs74820225; called by muse, mutect2, varscan2
- DAG1 | c.2343C>A p.G781= | Silent (SNP) | VAF 10/26 reads (38%) | called by muse, mutect2, varscan2
- KCTD14 | c.723C>T p.N241= | Silent (SNP) | VAF 20/46 reads (43%) | catalogued as rs368467821; called by muse, mutect2, varscan2
- NR0B1 | c.558G>A p.A186= | Silent (SNP) | VAF 8/10 reads (80%) | called by muse, varscan2
- PAXIP1 | c.378A>T p.G126= | Silent (SNP) | VAF 23/105 reads (22%) | called by muse, mutect2, varscan2
- PCLO | c.5769T>C p.H1923= | Silent (SNP) | VAF 23/91 reads (25%) | catalogued as COSV61621759; called by muse, mutect2, varscan2
- PDIA3 | c.117C>T p.I39= | Silent (SNP) | VAF 19/72 reads (26%) | catalogued as rs747839953; called by muse, mutect2, varscan2
- PDS5A | c.1329C>T p.V443= | Silent (SNP) | VAF 18/58 reads (31%) | catalogued as rs766740882; called by muse, mutect2, varscan2
- PEX16 | c.778C>T p.L260= | Silent (SNP) | VAF 28/83 reads (34%) | catalogued as rs769033920, COSV53802283; called by muse, mutect2, varscan2
- PRDM8 | c.327C>T p.N109= | Silent (SNP) | VAF 27/55 reads (49%) | called by muse, mutect2, varscan2
- PRDM9 | c.1683T>C p.F561= | Silent (SNP) | VAF 33/95 reads (35%) | called by muse, mutect2, varscan2
- PTPRG | c.2424T>C p.P808= | Silent (SNP) | VAF 38/94 reads (40%) | called by muse, mutect2, varscan2
- RBM15 | c.2058C>T p.S686= | Silent (SNP) | VAF 10/29 reads (34%) | called by muse, varscan2
- REXO1 | c.519T>G p.P173= | Silent (SNP) | VAF 23/44 reads (52%) | called by muse, mutect2, varscan2
- SETDB1 | c.3801C>T p.Y1267= (on ENST00000271640 / NM_001366417.1; = p.Y1266= on NM_012432.4) | Silent (SNP) | VAF 35/99 reads (35%) | catalogued as rs770434872, COSV54992583; called by muse, mutect2, varscan2
- SPDL1 | c.1068C>T p.V356= | Silent (SNP) | VAF 17/59 reads (29%) | catalogued as rs894605859; called by muse, mutect2, varscan2
- TFAP2B | c.165G>A p.P55= | Silent (SNP) | VAF 18/47 reads (38%) | called by muse, mutect2, varscan2
- ZC3H3 | c.1023T>C p.S341= | Silent (SNP) | VAF 30/107 reads (28%) | called by muse, mutect2, varscan2
- ZFAND2B | c.36G>A p.E12= | Silent (SNP) | VAF 48/117 reads (41%) | called by muse, mutect2, varscan2
- ZNF562 | c.906C>T p.S302= (on ENST00000453372 / NM_001130032.2; = p.S230= on NM_017656.4) | Silent (SNP) | VAF 64/204 reads (31%) | called by muse, mutect2, varscan2
- MAGEC3 | c.1124-130G>A | Intron (SNP) | VAF 17/19 reads (89%) | catalogued as rs1008085510; called by muse, mutect2, varscan2
- PRR34 | n.326G>C | RNA (SNP) | VAF 10/22 reads (45%) | catalogued as rs768072686, COSV61549124, COSV61549256; called by muse, varscan2
- SLIT3 | c.198-12222C>T | Intron (SNP) | VAF 17/50 reads (34%) | called by muse, mutect2, varscan2
